Surgical pathology report (de-identified scan), TCGA case TCGA-94-8491, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Washington University - Emory, specimen TCGA-94-8491-01A (Primary Tumor).

[page 1 of 4]
Final Surgical Pathology Report

Final Pathologic Diagnosis

- A. LYMPH NODES, RIGHT LEVEL 2, EXCISION:
- MULTIPLE LYMPH NODE FRAGMENTS NEGATIVE FOR METASTATIC CARCINOMA.
- B. LUNG, RIGHT LOWER LOBE, LOBECTOMY, B1FS:
- POORLY DIFFERENTIATED SQUAMOUS CELL CARCINOMA, 4.5 X 3.5 X 3.5 CM.
- BRONCHIAL AND VASCULAR MARGINS ARE NEGATIVE FOR CARCINOMA.
- ANGIOLYMPHATIC INVASION IDENTIFIED.
- THREE PERIBRONCHIAL LYMPH NODE POSITIVE FOR METASTATIC CARCINOMA WITH EXTRANODAL EXTENSION (3/3).
- SEE SYNOPTIC REPORT AND COMMENT.
- C. LYMPH NODES, RIGHT, LEVEL 7, EXCISION:
- MULTIPLE LYMPH NODE FRAGMENTS NEGATIVE FOR METASTATIC CARCINOMA.
- D. LYMPH NODES, RIGHT, LEVEL 4, EXCISION:
- THREE LYMPH NODES NEGATIVE FOR METASTATIC CARCINOMA (0/3).

Printed by:
Printed on:

[page 2 of 4]
Comment

Immunohistochemical stains for p63 shows strong nuclear staining in areas of squamous differentiation. These same areas are negative for TTF-1 stain. Although there is a small component showing focal glandular differentiation, the quantity is insufficient for a diagnosis of adenosquamous carcinoma.

Synoptic Worksheet

B. Right lower lobe; stitch at bronchial margin.:

Specimen:	Lobe(s) of lung: right lower
Procedure:	Lobectomy
Specimen Integrity:	Intact
Specimen Laterality:	Right
Tumor Site:	Lower lobe
Tumor Focality:	Unifocal
Histologic Type:	Squamous cell carcinoma
Histologic Grade:	G3: Poorly differentiated
Tumor Size:	Greatest dimension: 4.5 cm Additional dimension: 3.5 cm Additional dimension: 3.5 cm
Visceral Pleura Invasion:	Not identified
Tumor Extension:	Not identified
Bronchial Margin:	Uninvolved by invasive carcinoma Squamous cell carcinoma in situ (CIS) not identified at bronchial margin
Vascular Margin:	Uninvolved by invasive carcinoma
Parenchymal Margin:	Uninvolved by invasive carcinoma
Parietal Pleural Margin:	Not applicable
Chest Wall Margin:	Not applicable
Other Attached Tissue Margin:	Not applicable
All Margins Uninvolved By Invasive Carcinoma:	Distance of invasive carcinoma from closest margin: 5 mm Margin closest to invasive carcinoma:: bronchial
Treatment Effect:	Not applicable
Lymph-Vascular Invasion:	Present
Extranodal Extension:	Present
TNM Descriptors:	Not applicable
Primary Tumor (pT):	pT2a: Tumor greater than 3 cm, but 5 cm or less in greatest dimension surrounded by lung or visceral pleura, without bronchoscopic evidence of

[page 3 of 4]
invasion more proximal than the lobar bronchus (ie, not in the main bronchus); or Tumor 5 cm or less in greatest dimension with any of the following features of extent: involves main bronchus, 2 cm or more distal to the carina; invades the visceral pleura; associated with atelectasis or obstructive pneumonitis that extends to the hilar region but does not involve the entire lung

Regional Lymph Nodes (pN): pN1: Metastasis in ipsilateral peribronchial and/or ipsilateral hilar lymph nodes, and intrapulmonary nodes, including involvement by direct extension
Nodes examined: 6
Nodes involved: 3
Involved nodal station(s): peribronchial

Distant Metastasis (pM): Not applicable

Additional Pathologic Findings: None identified

Clinical History

Lung cancer. Right VATS with right lower lobectomy.

Specimen(s) Received

- A: Right level II lymph node.
- B: Right lower lobe; stitch at bronchial margin.
- C: Right level 7 lymph nodes
- D: Right level 4 lymph nodes

Gross Description

Specimen A is received in formalin, labeled with the patient's name, medical record number and identified as "right level 2 lymph node." The specimen consists of multiple fragments of adipose tissue measuring in aggregate 1.1 x 0.8 x 0.5 cm. The specimen is submitted entirely in cassette "A1." [REDACTED]

Specimen B is received fresh, labeled with the patient's name, medical record number and titled "right lower lobe, FS." The specimen consists of a single lung lobe that measures 18.5 x 15.0 x 3.0 cm and weighs 260 grams. The specimen contains a 4.5 x 3.5 x 3.5 cm well-circumscribed, firm, white mass. The mass appears to be 0.5 cm away from bronchial margin and 1.0 cm away from the vascular margin. The mass appears to abut but does not pucker the anterior pleura and is 0.5 cm away from the posterior pleura. No tumor is grossly seen in the bronchial or vascular system. No other masses or lesions are identified. Dictated by Dr. [REDACTED]

Specimen C is received in formalin, labeled with the patient's name and medical record number, and identified as "right level 7 lymph node." The specimen consists of a single piece of fibroadipose tissue measuring 1.8 x 1.3 x 0.5 cm. The specimen is submitted entirely in cassette "C1." [REDACTED]

Specimen D is received in formalin, labeled with the patient's name, medical record number, and identified as "right level 4 lymph node." The specimen consists of multiple fragments of fibroadipose tissue measuring in aggregate 1.1 x 0.6 x 0.4 cm. The specimen is submitted entirely in cassette "D1." [REDACTED]

Printed by:
Printed on:

[page 4 of 4]
CASSETTE SUMMARY:

B2: Mass in relation to posterior pleura
B3: Mass in relation to bronchus edge
B4: Vascular margin
B5: Mass in relation to the anterior pleura
B6: Single lymph node at bronchial edge, bivalved
B7: Mass in relation to the vasculature
B8: Mass in relation to bronchial system
B9: Mass in relation to normal lung parenchyma and representative section of mass
B10: Representative section of normal lung tissue

Intraoperative Consult Diagnosis

B1FS: BRONCHIAL MARGIN (FROZEN SECTION): NEGATIVE FOR CARCINOMA.

Frozen section results were communicated to the surgical team and were repeated back by

Microscopic Description

Microscopic examination performed.

Printed by:
Printed on:

Source: NCI Genomic Data Commons file 5b5c358a-eb23-42f2-984b-65abcea138c0 (TCGA-94-8491.C41A30FF-11D7-41EB-858A-D45300B7BEB3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).